FM case AD4443 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/76a0af4a-3339-4c3d-b696-e518c63c4606

Female, 58.4 years: Clear cell carcinoma (ICD-O-3 8310/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
